CGCI case HTMCP-02-15-01090 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7172e454-ce53-42fa-95e7-e88d531e1e49

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 448 days (1.2 years).

Diagnoses (1)
1. Large cell neuroendocrine carcinoma: ICD-O-3 morphology code: 8013/3; Tissue or organ of origin: Middle lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 61.1 years (22,307 days); Year of diagnosis: 2015; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 7th; AJCC clinical T: T2a; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 71 days.
   Pathology details: Lymph node involved site: Mediastinal; Lymph nodes positive: 2; Lymph nodes tested: 3.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 71 days; Disease response: With Tumor.
- Disease response: With Tumor.
- Follow-up contact recording only the day: day -3,938.

Other clinical attributes
- Day -3,938: Risk factors: HIV/AIDS.
- Day -3,938: Comorbidities: HIV/AIDS.
- Day 0: Weight: 56.7 kg; Height: 152.1 cm; BMI: 24.5; CD4 count: 280; Haart treatment indicator: Yes; HIV viral load: 40.
- Day 71: Nadir CD4 count: 180.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 43.

Biospecimens (3 samples)
- Sample HTMCP-02-15-01090-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-15-01090-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-15-01090-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Large cell Neuroendocine carcinoma; Tumor status: With tumor; Tobacco smoking age started: 18; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Middle lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 2004; Hbv test results: Negative; Hcv test results: Negative; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Fine needle aspiration biopsy; Days from index date to tumor sample procurement: 24; Other pos node location: Ipsilatera mediastinal and subcarinal.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-15-01090-01A-01E-11869:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-15-01090-01A-01S-11869:
- % tumour top: 80
- % tumour bottom: 80
